Somatic mutation profile of tumor specimen MMRF_2718_1_BM_CD138pos (aliquot MMRF_2718_1_BM_CD138pos_T1_KHS5U_L14816) from MMRF case MMRF_2718, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow.
Specimen MMRF_2718_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0b1e24d0-c722-4ba6-bd54-50207a01eb4d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2718_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2718_1_PB_WBC_C2_KHS5U_L14817; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4ca026e1-1c9b-425e-97ca-8be4ff08de24

The open-access MAF lists 110 somatic variants for this specimen: 34 protein-altering or splice-affecting, 10 silent, 66 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 41, Missense Mutation 31, Silent 10, 5'Flank 8, Intron 7, RNA 4, 5'UTR 4, Frame Shift Del 2, 3'Flank 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGAP33 | c.2958del p.D987Tfs*25 | Frame Shift Del (DEL) | VAF 12/38 reads (32%) | catalogued as rs776111468; called by mutect2, pindel, varscan2
- CACNA1B | c.1691C>T p.A564V | Missense Mutation (SNP) | VAF 53/112 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.909); catalogued as rs745437998, COSV53120434; called by muse, mutect2, varscan2
- CCN1 | c.971C>T p.T324M | Missense Mutation (SNP) | VAF 72/139 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as rs142599038, COSV71704387; called by muse, mutect2, varscan2
- FLT4 | c.2269G>A p.V757I | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.581); catalogued as COSV56110605; called by muse, mutect2, varscan2
- FOXG1 | c.1441G>T p.G481W | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); catalogued as COSV57395587; called by muse, mutect2, varscan2
- IGLV3-1 | c.302A>C p.E101A | Missense Mutation (SNP) | VAF 82/207 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs532827838; called by muse, mutect2, varscan2
- MARK1 | c.308A>T p.K103M | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV65070115; called by muse, mutect2, varscan2
- OTOGL | c.2165C>A p.A722D (on ENST00000547103; = p.A713D on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs769499824; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLD5 | c.1121G>A p.R374Q (on ENST00000442594; = p.R312Q on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.162); catalogued as COSV59163972; called by muse, mutect2
- VWF | c.1151G>A p.C384Y | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as rs775101417; called by muse, mutect2, varscan2
- ZNF513 | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 128/269 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); catalogued as rs1447833693, COSV52008270; called by muse, mutect2, varscan2
- ADARB1 | c.944T>C p.L315P | Missense Mutation (SNP) | VAF 62/131 reads (47%) | SIFT tolerated (0.35); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- AKAP11 | c.4864A>G p.K1622E | Missense Mutation (SNP) | VAF 33/271 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- ARFGEF1 | c.4463G>A p.C1488Y | Missense Mutation (SNP) | VAF 70/212 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- C1orf141 | c.475T>G p.Y159D | Missense Mutation (SNP) | VAF 115/257 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FGFR2 | c.1482A>T p.Q494H | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- FOXI2 | c.740G>T p.G247V | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- FRAS1 | c.10964C>T p.P3655L | Missense Mutation (SNP) | VAF 19/177 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HACD1 | c.289T>A p.F97I | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- INTS8 | c.1957A>T p.I653F | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- KCNK10 | c.397G>A p.D133N | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KIAA2026 | c.722G>T p.S241I | Missense Mutation (SNP) | VAF 124/247 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- KIF21A | c.3664G>C p.G1222R (on ENST00000361418 / NM_001378440.1; = p.G1209R on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); called by muse, mutect2
- LGALS8 | c.890T>C p.L297P (on ENST00000341872; = p.L339P on NM_006499.4) | Missense Mutation (SNP) | VAF 49/106 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAN2B1 | c.566C>T p.P189L | Missense Mutation (SNP) | VAF 100/214 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MKI67 | c.4258A>T p.T1420S | Missense Mutation (SNP) | VAF 89/190 reads (47%) | SIFT tolerated (0.7); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- PHF3 | c.3997+2T>C p.X1333_splice | Splice Site (SNP) | VAF 42/98 reads (43%) | called by muse, mutect2, varscan2
- SP6 | c.1103C>T p.A368V | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); called by mutect2, varscan2
- SRC | c.278A>G p.Y93C | Missense Mutation (SNP) | VAF 37/203 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TAS2R4 | c.820C>T p.P274S | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- TMEM121B | c.869G>A p.G290E | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- TOX | c.841G>T p.G281C | Missense Mutation (SNP) | VAF 135/237 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- USH2A | c.4738del p.Y1580Ifs*13 | Frame Shift Del (DEL) | VAF 63/148 reads (43%) | called by mutect2, pindel, varscan2
- ZMIZ1 | c.514G>A p.G172R | Missense Mutation (SNP) | VAF 107/220 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAM19 | c.1134C>T p.H378= | Silent (SNP) | VAF 26/55 reads (47%) | called by muse, mutect2, varscan2
- C8orf34 | c.315T>C p.G105= | Silent (SNP) | VAF 167/373 reads (45%) | called by muse, mutect2, varscan2
- DENND2D | c.1269G>A p.K423= | Silent (SNP) | VAF 6/90 reads (7%) | called by muse, mutect2
- FBLN2 | c.855G>A p.E285= | Silent (SNP) | VAF 45/86 reads (52%) | called by muse, mutect2, varscan2
- HECW1 | c.3375G>A p.Q1125= | Silent (SNP) | VAF 61/128 reads (48%) | called by muse, mutect2, varscan2
- IGLL5 | c.79C>T p.L27= | Silent (SNP) | VAF 22/59 reads (37%) | catalogued as rs777349722, COSV73249535, COSV73250343, COSV73250409; called by muse, mutect2, varscan2
- MYO5A | c.5094C>T p.A1698= | Silent (SNP) | VAF 32/104 reads (31%) | called by muse, mutect2, varscan2
- NKX2-4 | c.1011G>T p.G337= | Silent (SNP) | VAF 24/52 reads (46%) | called by muse, mutect2, varscan2
- NRAP | c.1794C>T p.A598= (on ENST00000359988 / NM_001322945.2; = p.A563= on NM_006175.4) | Silent (SNP) | VAF 17/133 reads (13%) | catalogued as rs147401897; called by muse, mutect2, varscan2
- UBR4 | c.3057C>T p.Y1019= | Silent (SNP) | VAF 65/138 reads (47%) | catalogued as rs145397189; called by muse, mutect2, varscan2
- AASDHPPT | c.*1088C>T | 3'UTR (SNP) | VAF 49/158 reads (31%) | catalogued as rs1042040851; called by muse, mutect2, varscan2
- ABCC9 | c.406+1622C>A | Intron (SNP) | VAF 21/60 reads (35%) | called by muse, mutect2, varscan2
- ABI2 | c.*3815G>C | 3'UTR (SNP) | VAF 58/116 reads (50%) | called by muse, mutect2, varscan2
- AC022784.2 | n.203G>A | RNA (SNP) | VAF 10/59 reads (17%) | called by muse, mutect2, varscan2
- AC022905.1 | n.763G>A | RNA (SNP) | VAF 12/84 reads (14%) | called by muse, mutect2
- ADGB | c.*156G>A | 3'UTR (SNP) | VAF 38/87 reads (44%) | called by muse, mutect2, varscan2
- AL353804.4 | chrX:73824918 A>C | 5'Flank (SNP) | VAF 10/34 reads (29%) | called by muse, mutect2, varscan2
- ARMC8 | c.*659_*662del | 3'UTR (DEL) | VAF 6/26 reads (23%) | called by pindel, varscan2
- ARPP21 | c.261+1599A>G | Intron (SNP) | VAF 31/72 reads (43%) | called by muse, mutect2, varscan2
- ATP2B2 | chr3:10325360 A>G | 3'Flank (SNP) | VAF 8/81 reads (10%) | called by muse, mutect2, varscan2
- ATP8A2 | c.*5220T>G | 3'UTR (SNP) | VAF 41/91 reads (45%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021371 A>G | 5'Flank (SNP) | VAF 64/141 reads (45%) | called by muse, mutect2, varscan2
- BMP6 | c.*922A>T | 3'UTR (SNP) | VAF 21/97 reads (22%) | called by muse, mutect2, varscan2
- BNIP3P1 | n.743T>A | RNA (SNP) | VAF 18/164 reads (11%) | called by muse, mutect2
- CCDC6 | c.*2207G>A | 3'UTR (SNP) | VAF 21/71 reads (30%) | called by muse, mutect2, varscan2
- CCND3 | c.711+142T>C | Intron (SNP) | VAF 45/96 reads (47%) | called by muse, mutect2, varscan2
- CDC25A | c.*456T>G | 3'UTR (SNP) | VAF 9/83 reads (11%) | called by muse, mutect2, varscan2
- CDH20 | c.*884C>A | 3'UTR (SNP) | VAF 32/60 reads (53%) | called by muse, mutect2, varscan2
- CDS2 | c.*7284A>C | 3'UTR (SNP) | VAF 13/123 reads (11%) | called by muse, mutect2, varscan2
- COMMD10 | c.*349T>C | 3'UTR (SNP) | VAF 34/78 reads (44%) | called by muse, mutect2, varscan2
- CYP4F8 | c.1314+40C>T | Intron (SNP) | VAF 57/103 reads (55%) | catalogued as rs1237797008; called by muse, mutect2, varscan2
- DIRAS2 | c.*349G>A | 3'UTR (SNP) | VAF 55/114 reads (48%) | called by muse, mutect2, varscan2
- FAF2 | chr5:176447642 A>G | 5'Flank (SNP) | VAF 15/107 reads (14%) | called by muse, mutect2, varscan2
- FEZF2 | c.*281C>A | 3'UTR (SNP) | VAF 31/75 reads (41%) | called by muse, mutect2, varscan2
- FLI1 | c.*1108T>C | 3'UTR (SNP) | VAF 37/165 reads (22%) | called by muse, mutect2, varscan2
- GABRG3 | c.270+42C>A | Intron (SNP) | VAF 18/121 reads (15%) | called by muse, mutect2, varscan2
- GRID2 | c.*483C>T | 3'UTR (SNP) | VAF 12/100 reads (12%) | catalogued as rs1366633777; called by muse, mutect2, varscan2
- HMCN2 | c.*140C>A | 3'UTR (SNP) | VAF 9/59 reads (15%) | catalogued as rs1168911529; called by muse, mutect2, varscan2
- HRH4 | c.*1540G>A | 3'UTR (SNP) | VAF 6/22 reads (27%) | called by muse, mutect2
- IGHV3-74 | c.-43C>G | 5'UTR (SNP) | VAF 47/57 reads (82%) | catalogued as rs746336721; called by muse, mutect2, varscan2
- KLB | c.*943A>C | 3'UTR (SNP) | VAF 4/13 reads (31%) | called by muse, mutect2, varscan2
- KLHL1 | c.*119T>C | 3'UTR (SNP) | VAF 58/142 reads (41%) | called by muse, mutect2, varscan2
- KRTAP2-3 | c.*247del | 3'UTR (DEL) | VAF 18/54 reads (33%) | catalogued as rs968973148; called by mutect2, varscan2
- LAD1 | c.39-1812G>A | Intron (SNP) | VAF 15/120 reads (13%) | called by muse, mutect2, varscan2
- LLGL1 | c.*866T>C | 3'UTR (SNP) | VAF 8/18 reads (44%) | called by muse, mutect2
- LNPEP | c.*7967C>T | 3'UTR (SNP) | VAF 22/104 reads (21%) | called by muse, mutect2, varscan2
- METAP2 | c.*214T>C | 3'UTR (SNP) | VAF 13/78 reads (17%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851315 C>G | 5'Flank (SNP) | VAF 78/87 reads (90%) | catalogued as rs537569481; called by muse, mutect2, varscan2
- MOB3B | c.*1627del | 3'UTR (DEL) | VAF 11/92 reads (12%) | called by mutect2, pindel, varscan2
- MYC | c.-158G>C | 5'UTR (SNP) | VAF 38/76 reads (50%) | catalogued as COSV52370124, COSV52375531; called by muse, varscan2
- MYC | c.-116A>G | 5'UTR (SNP) | VAF 42/80 reads (53%) | catalogued as COSV52369238; called by muse, varscan2
- NAP1L4 | c.*219T>C | 3'UTR (SNP) | VAF 84/180 reads (47%) | called by muse, mutect2, varscan2
- NFIB | c.*6433T>G | 3'UTR (SNP) | VAF 18/45 reads (40%) | called by muse, mutect2, varscan2
- NTM-AS1 | n.2560A>T | RNA (SNP) | VAF 25/96 reads (26%) | called by muse, mutect2, varscan2
- NTRK2 | c.*900G>C | 3'UTR (SNP) | VAF 58/121 reads (48%) | called by muse, mutect2, varscan2
- NUP58 | c.1436-1016C>A | Intron (SNP) | VAF 10/29 reads (34%) | called by muse, mutect2, varscan2
- OLFML2B | c.*411T>G | 3'UTR (SNP) | VAF 14/76 reads (18%) | called by muse, mutect2, varscan2
- OSTM1 | c.*2682T>G | 3'UTR (SNP) | VAF 13/37 reads (35%) | called by muse, mutect2, varscan2
- OTUD3 | c.*1231A>C | 3'UTR (SNP) | VAF 20/114 reads (18%) | called by muse, mutect2, varscan2
- PCDH18 | c.*1411T>C | 3'UTR (SNP) | VAF 31/87 reads (36%) | called by muse, mutect2, varscan2
- RBMS3 | c.*277A>T | 3'UTR (SNP) | VAF 8/49 reads (16%) | called by muse, mutect2, varscan2
- RN7SL860P | chr19:22600191 C>G | 5'Flank (SNP) | VAF 14/28 reads (50%) | called by muse, varscan2
- RND3 | c.*331_*332insGTT | 3'UTR (INS) | VAF 16/38 reads (42%) | catalogued as COSV55723412; called by mutect2, pindel, varscan2
- SLC44A5 | c.*1571T>C | 3'UTR (SNP) | VAF 33/68 reads (49%) | called by muse, mutect2, varscan2
- SLITRK2 | c.-1728C>T | 5'UTR (SNP) | VAF 64/66 reads (97%) | called by muse, mutect2, varscan2
- SMARCAD1 | c.*52C>T | 3'UTR (SNP) | VAF 105/231 reads (45%) | called by mutect2, varscan2
- SMARCAD1 | c.*56del | 3'UTR (DEL) | VAF 100/256 reads (39%) | called by mutect2, pindel, varscan2
- SOX2 | c.*1117C>T | 3'UTR (SNP) | VAF 29/92 reads (32%) | called by muse, mutect2, varscan2
- SPRYD3 | c.*316G>A | 3'UTR (SNP) | VAF 59/137 reads (43%) | called by muse, mutect2, varscan2
- TJP1 | c.*1555C>T | 3'UTR (SNP) | VAF 20/184 reads (11%) | catalogued as rs531302604; called by muse, mutect2, varscan2
- TK2 | chr16:66550351 A>G | 5'Flank (SNP) | VAF 164/340 reads (48%) | called by muse, mutect2, varscan2
- TMSB4X | chrX:12975566 C>T | 5'Flank (SNP) | VAF 148/157 reads (94%) | catalogued as rs1457788669; called by muse, mutect2, varscan2
- TNFRSF19 | c.*1704del | 3'UTR (DEL) | VAF 11/94 reads (12%) | catalogued as rs544006252; called by mutect2, pindel, varscan2
- TNFRSF19 | c.*1699T>A | 3'UTR (SNP) | VAF 12/93 reads (13%) | called by mutect2, varscan2
- VRK2 | chr2:58159919 A>C | 3'Flank (SNP) | VAF 28/92 reads (30%) | called by muse, mutect2, varscan2
- WNT5A | chr3:55487323 C>A | 5'Flank (SNP) | VAF 10/63 reads (16%) | called by muse, mutect2, varscan2
